CCDI case PBCVHG — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS.
https://portal.gdc.cancer.gov/cases/ddf7fb52-d8d6-4f4a-a3ba-0e238b4729cb

Demographics
Sex at birth: female.

Biospecimens (1 sample)
- Sample 0E1202: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
